Somatic mutation profile of tumor specimen 0DWYWO from CCDI case PBCPWV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,093 days).
Specimen 0DWYWO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 183216f2-4395-48e2-bc08-1c274e34005a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a120f529-e06f-42c5-8cd5-586badc5e0ca

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBX1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 314/822 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs200609477, COSV52547358; called by muse, varscan2
- ADAM28 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 194/556 reads (35%) | called by muse, varscan2
- DHX38 | c.183G>A p.E61= | Silent (SNP) | VAF 268/724 reads (37%) | called by muse, varscan2
